Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5402, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5402-01A (Primary Tumor).

[page 1 of 2]
FINAL CLINICAL QUESTION: Left renal mass.

PROCEDURE: Left radical nephrectomy, Resection of part of psoas muscle, gastrorrhaphy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

CYTOGENETICS TESTS: Not answered.

AMENDED/CORRECTED REPORT:

Reason: 1) to change the pathologic T-stage, which was inadvertently reported as T3a rather than T4 (based on 7th Ed. AJCC staging criteria) and 2) to report the presence of one renal sinus small renal vein tumor thrombus, which was identified at the time of initial signout of the case but was inadvertently omitted from the report. No other changes have been to the report.

Changes were made in the Final Diagnosis and Synoptic fields.

This amended report supersedes all prior reports under this accession number and should be filed with the original report.

FINAL DIAGNOSIS:

PART 1: LEFT KIDNEY, PROXIMAL URETER, AND LEFT ADRENAL GLAND, RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, HEMORRHAGE AND NECROSIS AND FOCAL SARCOMATOID DEDIFFERENTIATION (SLIDES 1J, 1V).
- B. FUHRMAN NUCLEAR GRADE IS PREDOMINANTLY 3 TO FOCALLY 4 OUT OF 4.
- C. MAXIMAL DIAMETER OF THE NEOPLASM IS 25 CM.
- D. MULTIFOCAL EXTRACAPSULAR EXTENSION IS PRESENT IN PERIRENAL ADIPOSE TISSUE. CARCINOMA ALSO FOCALLY INFILTRATES ADRENAL GLAND VIA DIRECT EXTENSION (SLIDE 1D).
- E. NO MAIN RENAL VEIN TUMOR THROMBUS IS IDENTIFIED.
- F. FOCAL TUMOR EMBOLUS IS PRESENT OCCLUDING A RENAL SINUS VEIN IDENTIFIED MICROSCOPICALLY.
- G. ALL SURGICAL RESECTION MARGINS, GEROTA'S FASCIA, MAIN RENAL VEIN, PROXIMAL URETER, AND RENAL ARTERY ARE FREE OF NEOPLASM.
- H. NON-NEOPLASTIC KIDNEY SHOWS MILD - MODERATE GLOMERULAR HYPERTROPHY, MILD ARTERIAL SCLEROSIS, FOCAL MILD SUBCAPSULAR TUBULAR ATROPHY, AND FOCAL MILD INTERSTITIAL FIBROSIS (PAS, SILVER, AND TRICHROME STAINS).
- I. NO LYMPH NODES ARE IDENTIFIED.
- J. TNM PATHOLOGIC STAGE (AJCC 7TH EDITION): pT4 NX MX (See synoptic).

PART 2: PORTION OF STOMACH, EXCISION –

- A. BENIGN GASTRIC TISSUE LINED BY OXYNTIC MUCOSA.
- B. NO EVIDENCE OF MALIGNANCY.

PART 3: PSOAS MUSCLE, POSTERIOR MARGIN, RESECTION –

- A. BENIGN STRIATED MUSCLE WITH ORGANIZING HEMORRHAGE.
- B. NO EVIDENCE OF MALIGNANCY.

[page 2 of 2]
CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Radical nephrectomy
LATERALITY: Left
TUMOR SITE: Upper pole

Middle
Lower pole
FOCALITY: Multifocal

TUMOR SIZE: Greatest dimension: 25 cm
Additional dimensions: 13 x 8 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor extension into perinephric tissues

Tumor extension into adrenal
HISTOLOGIC TYPE: Sarcomatoid carcinoma arising in renal cell carcinoma
Subtype and % of sarcomatoid element: Clear cell (conventional); sarcomatoid (25%)

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G4

PATHOLOGIC STAGING (pTNM): pT4
pNX
Number of regional lymph nodes examined: 0
pMX

MARGINS: Margins uninvolved by invasive carcinoma
ADRENAL GLAND: Direct invasion (T4)

LYMPH-VASCULAR INVASION (LVI): Present/identified

ADDITIONAL PATHOLOGIC FINDINGS: None identified

KIDNEY-RESIDUAL TUMOR (R): R0

Comment: Most of the carcinoma is Fuhrman grade 3; focally the carcinoma is Fuhrman grade 4.

Source: NCI Genomic Data Commons file 762ebfdb-b283-443b-a360-f4cdb2778891 (TCGA-B0-5402.2B70BF77-1990-40CD-82F3-1390A8C883F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).